TCGA case TCGA-CG-4304 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8e005891-d6fe-4fee-a699-971fee4e70f1

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 84 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; ICD-10 code: C16.0; Tissue or organ of origin: Cardia, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 84.9 years (31,017 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T2a; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Lymph nodes positive: 0; Lymph nodes tested: 18.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-4304-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.3; Intermediate dimension: 1; Shortest dimension: 0.5.
  Slide TCGA-CG-4304-01A-01-TS1: Section location: Top; Percent tumor cells: 85; Percent tumor nuclei: 75; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-CG-4304-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-CG-4304-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-4304-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Adenocarcinoma, Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Anatomic organ subdivision: Cardia/Proximal; Lymph nodes examined: Yes; Cancer procurement city: Hamburg.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), time not recorded; disease-specific survival: no event (censored), time not recorded; progression-free interval: no event (censored), time not recorded.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-4304-01A-01D-1155-01): tumor purity 0.58, ploidy 1.97, whole-genome doublings 0.
